Surgical pathology report (de-identified scan), TCGA case TCGA-3U-A98H, project TCGA-MESO (Mesothelioma), tissue source site University of Chicago, specimen TCGA-3U-A98H-01A (Primary Tumor).

[page 1 of 6]
Sample #

Gender: Male

DOB:

Race: White

Report Date:

Tissue Procurement Date:

ICD-O-3

Mesothelioma, epithelioid,
malignant 9052h3

Site: Pleura NOS C58.4

9/3/12/14

Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Right chest wall; excisional biopsy:

- Skin and subcutis with ulceration, chronic inflammation and marked foreign body giant cell reaction to talc, suture granuloma, negative for tumor, see comment.

B. Right chest wall #2; excisional biopsy:

- Malignant mesothelioma involving dense fibrous tissue and extending into one lymph node. (1/1)

C. Lymph node, level 4R ; biopsy:

- One lymph node, positive for metastatic malignant mesothelioma.(1/1)

D. Diaphragm; biopsy:

- Malignant mesothelioma involving skeletal muscle.

E. Pericardium; excisional biopsy:

-Pericardium with full-thickness involvement by malignant mesothelioma.

F. Hilar nodule; biopsy:

- Lung tissue with parenchymal involvement by malignant mesothelioma.

G. Pleura and diaphragm; pleurectomy:

- Malignant mesothelioma, biphasic type extending into lung parenchyma, endothoracic fascia and diaphragmatic skeletal muscle, see cancer staging below.
- Extensive foreign body giant cell reaction to crystalline material (talc).

Thoracic Mesothelioma Pathologic Parameters

Pleura/Pericardium, Resection

MACROSCOPIC

Specimen Type: Pleural resection, diaphragm, pericardium, lung tissue.

Tumor Site: Right pleura.

Tumor Configuration and Size: Diffuse, maximum thickness: 2.8 cm

MICROSCOPIC: Biphasic mesothelioma (epithelioid 95%, sarcomatoid 5%)

[page 2 of 6]
Tumor Extension:

Parietal pleura with focal involvement of ipsilateral visceral pleura

Into but not through diaphragm

Lung parenchyma

Endothoracic fascia

Into and through the pericardium

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): present.

Margins: Cannot be assessed

Additional Pathologic Findings: extensive foreign body giant cell reaction to talc.

*Pathologic Staging (pTNM): pT4, N2, MX.

Primary Tumor (pT)

pT4: Tumor (locally advanced technically unresectable) involves any of the ipsilateral pleural surfaces, with at least 1 of the following: diffuse or multifocal invasion of soft tissues of the chest wall, any involvement of rib, invasion through the diaphragm to the peritoneum, invasion of any mediastinal organ(s), direct extension to the contralateral pleura, invasion into the spine, extension to the internal surface of the pericardium, pericardial effusion with positive cytology, invasion of the myocardium.

Regional Lymph Nodes (pN)

pN2: Metastases in the subcarinal lymph node(s) and/or the ipsilateral internal mammary or mediastinal lymph node(s)

Specify: Number examined: 2 (4R and chest wall)

Number involved: 2

Distant Metastasis (pM): pMX: Cannot be assessed

*Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for pleural mesothelioma of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Comment

Part A: An immunostain for CAM5.2 on selected sections supports the diagnosis.
(Control appropriate)

xxxx

[], M.D.

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], M.D.

Electronically Signed Out by [] M.D.

[page 3 of 6]
Clinical History:

The patient is a [] year-old male with malignant mesothelioma undergoing a right thoracotomy.

Specimens Received:

- A: Right chest wall
- B: Right chest wall #2
- C: 4R lymph node
- D: Diaphragm
- E: Pericardium
- F: Hilar nodule; biopsy
- G: Pluera and diaphragm

Gross Description:

The specimens are received in seven containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "right chest wall FS". Received fresh for frozen section diagnosis is an ellipse of tan-white skin measuring 6 x 2 cm excised to a depth of 5 cm. The deep margin is inked black. Sectioning shows a central area of ill-defined rubbery pink-white fibrous tissue measuring 2.5 x 1.8 x 0.7 cm. A representative portion is frozen and read as "foreign body reaction to embedded crystalline material", per Dr. []. The frozen section remnant is submitted entirely in cassette A1 FS. The remainder of the subcutaneous tissue is soft yellow and white. Additional representative sections of the specimen are submitted in cassettes A2-A4.

B. The second container is additionally identified as, "right chest wall #2". Received fresh for frozen section diagnosis is a 2 x 1.5 x 1 cm piece of firm red-white tissue. A representative section is frozen and read as "mesothelioma in dense fibrous tissue; no skeletal muscle is seen", per Dr. []. The frozen section remnant is submitted entirely in cassette B1 FS. The remaining specimen is entirely submitted in cassette B2.

C. The third container is additionally identified as, "4R lymph node". Received fresh for frozen section diagnosis are multiple fragments of soft yellow and firm tan-brown tissue measuring 1.5 cm in aggregate. The firm tissue is entirely frozen and read as "metastatic tumor consistent with mesothelioma", per Dr. []. The frozen section remnant is submitted entirely in cassette C1 FS.

D. The fourth container is additionally identified as, "diaphragm". Received fresh for frozen section diagnosis is a 1.6 x 0.7 x 0.2 cm piece of rubbery dusky tan tissue. 2 representative cross sections are frozen and read as "skeletal muscle with focal atrophy and fibrosis, no tumor", per Dr. []. The

[page 4 of 6]
frozen section remnant is submitted entirely in cassette D1 FS. The remainder of the tissue is submitted entirely in cassette D2.

E. The fifth container is additionally identified as, "pericardium". Received fresh and placed in formalin is a 3.5 x 3.4 cm piece of fibrous rubbery white tissue with an attached blue suture. There is no designation of the suture on the requisition form or specimen container. Also attached is a 2.2 x 0.8 x 0.4 cm piece of shaggy pink and soft yellow tissue. In the central aspect of the white tissue is a cluster of firm white nodules measuring 2.5 x 2.2 x 0.3 cm. multiple representative sections, including the entire cluster of nodules, are submitted in cassettes E1 and E2.

F. The sixth container is additionally identified as, "hilar nodule". Received fresh and placed in formalin is an ovoid rubbery white nodule measuring 1.6 x 1.4 x 1.1 cm. sectioning shows a solid white glistening tissue. Representative sections are submitted in cassette F1.

G. The seventh container is additionally identified as, "pleura and diaphragm". Received fresh and placed in formalin is a 410 g, 450 mL the specimen. There are 2 large pieces and an aggregate smaller pieces measuring 5.5 x 5 x 0.4 cm. One larger piece measures 22 x 20 cm with a thicknesses varying from 0.2-3.0 cm. The second larger piece measures 23 x 17 cm with variable thicknesses ranging from 0.3-2.8 cm. On both larger pieces, are diffusely scattered rubbery white nodules ranging from 0.1 x 0.1 x 0.1 cm to 1.8 x 1.4 x 0.5 cm. A majority of the nodules are less than 0.5 cm in greatest dimension. Of note, there is no suture material on or designation of the specimen. The nodules are within fibrous rubbery tan and pink tissue, lobulated soft yellow tissue and coating identifiable red-brown and soft skeletal muscle.

Multiple gross photographs are submitted.

Block summary:

G1-G3: Representative sections of larger nodules

C4-G10: Representative sections of remainder of specimen (tumor with skeletal muscle in G8-G10)

xxx

[]

Intraoperative Consult Diagnosis:

A1FS: "foreign body reaction to embedded crystalline material", per Dr. []

B1FS: "mesothelioma in dense fibrous tissue; no skeletal muscle is seen", per Dr. [].

C1FS: "metastatic tumor consistent with mesothelioma", per Dr. []

D1FS: "skeletal muscle with focal atrophy and fibrosis, no tumor", per Dr. []

[page 5 of 6]
Pathologic Discrepancy Form (Open Clinica):

Patient is histologically biphasic, but the frozen sample being sent to TCGA contains only epithelioid.

TSS - dx discrepancy form
states TCGA tumor to be
epithelioid, rather than biphasic,
cca

[page 6 of 6]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Tissue Source Site (TSS), _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Biphasic Mesothelioma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Epithelioid Mesothelioma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Epithelioid component is present only on frozen slide.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 4a4b42d7-691a-4c78-b3a9-cc20585bb8a8 (TCGA-3U-A98H.F5BDA912-7354-442E-956A-A986D219F2D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).